Somatic mutation profile of tumor specimen TCGA-77-A5G6-01A (aliquot TCGA-77-A5G6-01A-11D-A27K-08) from TCGA case TCGA-77-A5G6, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.3 years (24,215 days).
Specimen TCGA-77-A5G6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53f330a6-5c03-45bd-a5f2-1ab9b2286f6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-A5G6-10A (Blood Derived Normal), aliquot TCGA-77-A5G6-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8cc74d5-6cb5-4fd8-995c-5cbc945c4599

The open-access MAF lists 570 somatic variants for this specimen: 417 protein-altering or splice-affecting, 134 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 353, Silent 134, Nonsense Mutation 29, Frame Shift Del 13, Intron 11, Splice Site 11, Frame Shift Ins 5, RNA 5, Splice Region 3, 3'UTR 2, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.1907G>A p.G636D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559563141, COSV61632991; ClinVar: likely pathogenic; called by muse, mutect2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 46/190 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 75/156 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 38/65 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.4165G>T p.V1389L | Missense Mutation (SNP) | VAF 131/174 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100383636, COSV60622209; called by muse, mutect2, varscan2
- ABCA9 | c.3265G>T p.D1089Y | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100383637; called by muse, mutect2, varscan2
- ABCB1 | c.1417G>C p.V473L | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV99714755; called by muse, mutect2, varscan2
- ABCC2 | c.4509-2A>T p.X1503_splice | Splice Site (SNP) | VAF 40/86 reads (47%) | catalogued as COSV100966782; called by muse, mutect2, varscan2
- ABR | c.1905G>C p.R635S (on ENST00000302538 / NM_021962.5; = p.R598S on NM_001092.5) | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as COSV99348779; called by muse, mutect2, varscan2
- AC006059.2 | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 83/138 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs766510697, COSV100046082; called by muse, mutect2, varscan2
- AC100868.1 | c.1522C>A p.L508M | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.287); catalogued as COSV99227191; called by muse, mutect2, varscan2
- ACADS | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as CM164824, COSV99656884; called by muse, mutect2, varscan2
- ACKR1 | c.296T>A p.L99Q | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100929701, COSV63672358; called by muse, mutect2, varscan2
- ADAMTS12 | c.2566C>A p.R856S | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV100711781; called by muse, mutect2
- ADAMTS16 | c.2237C>T p.T746M | Missense Mutation (SNP) | VAF 108/245 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs560563999, COSV56984274; called by muse, mutect2, varscan2
- ADAMTS4 | c.1223G>C p.S408T | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1558075720, COSV100917607; called by muse, mutect2, varscan2
- ADPRH | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100813377; called by muse, mutect2, varscan2
- ADRB3 | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV100800030; called by muse, mutect2, varscan2
- AFF4 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV99535524; called by muse, mutect2, varscan2
- AFMID | c.620A>T p.Q207L | Missense Mutation (SNP) | VAF 150/184 reads (82%) | SIFT tolerated (0.43); PolyPhen benign (0.059); catalogued as COSV100015147, COSV59976157; called by muse, mutect2, varscan2
- AHNAK | c.13859G>T p.G4620V | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99950136; called by muse, mutect2, varscan2
- AHSG | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99890088, COSV99890479; called by muse, mutect2, varscan2
- AKR1D1 | c.961C>A p.P321T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99653328; called by muse, mutect2, varscan2
- AMER1 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 33/36 reads (92%) | catalogued as COSV57669035; called by muse, mutect2, varscan2
- AMPD1 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV100815333; called by muse, mutect2, varscan2
- ANAPC5 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99946573; called by muse, mutect2, varscan2
- ANK2 | c.11083G>T p.E3695* | Nonsense Mutation (SNP) | VAF 52/84 reads (62%) | catalogued as COSV100004716; called by muse, mutect2, varscan2
- ANK3 | c.10263A>T p.Q3421H | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV99782933; called by muse, mutect2, varscan2
- ANO5 | c.811T>A p.Y271N | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100202351; called by muse, mutect2, varscan2
- AOC1 | c.1086C>A p.H362Q | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.757); catalogued as COSV100711052; called by muse, mutect2, varscan2
- AOC1 | c.2251G>T p.V751L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100711053; called by muse, mutect2
- APBB1IP | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 199/333 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100774515; called by muse, mutect2, varscan2
- APBB1IP | c.1496A>T p.N499I | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as COSV100882290; called by muse, mutect2, varscan2
- AQP12A | c.330G>T p.M110I | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100539037; called by muse, mutect2, varscan2
- ARHGAP36 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 18/23 reads (78%) | catalogued as COSV99358325; called by muse, mutect2, varscan2
- ARID5B | c.334T>G p.W112G | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99690630; called by muse, mutect2, varscan2
- ASPHD2 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780554272, COSV99313543, COSV99313649; called by muse, mutect2, varscan2
- ASTN1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as rs766331604, COSV99923464; called by muse, mutect2, varscan2
- ATN1 | c.637C>G p.P213A | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as COSV100755997; called by muse, mutect2, varscan2
- ATP8A1 | c.375A>T p.K125N | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV100047535; called by muse, mutect2, varscan2
- BCL9L | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1265410454, COSV99420338; called by muse, mutect2, varscan2
- BCLAF1 | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as rs765477465, COSV62140396, COSV62144399; called by mutect2, varscan2
- BGN | c.188G>T p.C63F | Missense Mutation (SNP) | VAF 88/103 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782211881, COSV100525341; called by muse, mutect2, varscan2
- BICRAL | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100018601; called by muse, mutect2, varscan2
- BLK | c.543C>G p.C181W | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV99377769; called by muse, mutect2, varscan2
- BPIFA1 | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.812); catalogued as rs745983430, COSV100845669; called by muse, mutect2, varscan2
- BTN2A2 | c.549G>T p.R183S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as COSV100760612; called by muse, mutect2, varscan2
- C7 | c.1535G>T p.C512F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100496746; called by muse, mutect2, varscan2
- C9orf135 | c.629C>A p.A210D | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.59); catalogued as COSV65874600; called by muse, mutect2, varscan2
- CA6 | c.71C>A p.T24N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101077732; called by muse, mutect2, varscan2
- CACNA1E | c.1609C>A p.H537N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as COSV100705800; called by muse, varscan2
- CAMTA1 | c.3217G>T p.A1073S | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs752362812, COSV100352766; called by muse, mutect2, varscan2
- CAVIN2 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100414402, COSV58423531; called by muse, mutect2, varscan2
- CBX2 | c.1565C>G p.T522S | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99490989, COSV99491066; called by muse, mutect2, varscan2
- CCDC102B | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 82/256 reads (32%) | catalogued as COSV100102794, COSV100105217; called by muse, mutect2, varscan2
- CCER1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62645768; called by muse, mutect2, varscan2
- CD207 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101338575, COSV101338605; called by muse, mutect2, varscan2
- CDC42BPA | c.5035A>G p.S1679G (on ENST00000334218 / NM_001366019.2; = p.S1666G on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs746579028, COSV100507123; called by muse, mutect2, varscan2
- CDH20 | c.1699C>A p.Q567K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as COSV99406759; called by muse, mutect2, varscan2
- CDH22 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as rs757011961, COSV100953005; called by muse, mutect2, varscan2
- CDH23 | c.5328C>A p.N1776K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as rs371522191, COSV99824436; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELF5 | c.1181G>C p.R394P | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV99486276; called by muse, mutect2, varscan2
- CEP104 | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 30/63 reads (48%) | catalogued as COSV100986749, COSV65517010; called by muse, mutect2, varscan2
- CEP89 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99994134; called by muse, mutect2, varscan2
- CEPT1 | c.263T>C p.I88T | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV100853513; called by muse, mutect2, varscan2
- CHRNA6 | c.984C>A p.H328Q | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99373474; called by muse, mutect2, varscan2
- CIITA | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100162718, COSV60862733; called by muse, mutect2, varscan2
- CLDN6 | c.176C>A p.T59N | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100172422; called by muse, varscan2
- CNTNAP5 | c.706G>T p.G236W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101444370; called by muse, mutect2, varscan2
- COIL | c.905T>G p.L302R | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.295); catalogued as COSV99538451; called by muse, mutect2, varscan2
- COL16A1 | c.2621G>T p.G874V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99595749; called by muse, mutect2, varscan2
- COL19A1 | c.1810C>G p.P604A | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.698); catalogued as COSV100507743; called by muse, mutect2, varscan2
- CR1 | c.5162G>C p.G1721A | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100888101; called by muse, mutect2, varscan2
- CRACD | c.2788C>A p.P930T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.56); catalogued as COSV99949696, COSV99950181; called by muse, mutect2, varscan2
- CRACD | c.2789C>A p.P930H | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as COSV99950090; called by muse, mutect2, varscan2
- CRB1 | c.2009G>C p.C670S | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100958104; called by muse, mutect2, varscan2
- CRISPLD1 | c.336G>T p.L112F | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100082564; called by muse, mutect2, varscan2
- CSF2RB | c.458G>A p.S153N | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as rs1294229588, COSV99454624; called by muse, mutect2, varscan2
- CSMD3 | c.4092C>A p.Y1364* (on ENST00000297405 / NM_001363185.1; = p.Y1260* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99851202; called by muse, mutect2, varscan2
- CSMD3 | c.2635G>A p.D879N (on ENST00000297405 / NM_001363185.1; = p.D775N on NM_052900.3) | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.464); catalogued as COSV52209212, COSV99828376; called by muse, mutect2, varscan2
- CST4 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV54149509, COSV99463495; called by muse, mutect2, varscan2
- CTSL | c.860G>C p.S287T | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100446768; called by muse, mutect2, varscan2
- CYP11B2 | c.169A>T p.R57W | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100011465; called by muse, mutect2, varscan2
- DAW1 | c.993T>A p.S331R | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV100006609; called by muse, mutect2, varscan2
- DCT | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 121/193 reads (63%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100986159, COSV100986326; called by muse, mutect2, varscan2
- DDR2 | c.1604G>A p.G535D | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.341); catalogued as rs752400564, COSV100906950; called by muse, mutect2, varscan2
- DDX23 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100340021; called by muse, mutect2, varscan2
- DGKI | c.959C>G p.P320R | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55949015, COSV99937841, COSV99938434; called by muse, mutect2, varscan2
- DICER1 | c.2723G>T p.G908V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100602611, COSV100602656; called by muse, mutect2, varscan2
- DLGAP1 | c.1917G>T p.R639S | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as COSV100234552; called by muse, mutect2, varscan2
- DLL3 | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV52695203, COSV99219597; called by muse, mutect2, varscan2
- DMBT1 | c.5578C>A p.H1860N (on ENST00000338354 / NM_001377530.1; = p.H1103N on NM_004406.3) | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100354427; called by muse, mutect2, varscan2
- DMXL1 | c.3440G>T p.R1147I | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV100225229; called by muse, mutect2, varscan2
- DNAH10 | c.5928C>G p.F1976L (on ENST00000409039; = p.F1915L on NM_207437.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as rs751485201, COSV101292967; called by muse, mutect2, varscan2
- DNAH11 | c.8026C>A p.L2676I | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.047); catalogued as rs957859983, COSV100181381; called by muse, mutect2, varscan2
- DNAH5 | c.11212G>T p.E3738* | Nonsense Mutation (SNP) | VAF 21/42 reads (50%) | catalogued as COSV54205533, COSV99455398; called by muse, mutect2, varscan2
- DNAH5 | c.11212-1G>T p.X3738_splice | Splice Site (SNP) | VAF 19/40 reads (48%) | catalogued as COSV99454197; called by muse, mutect2, varscan2
- DOCK2 | c.4010G>T p.R1337M | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99916184; called by muse, mutect2, varscan2
- DOCK3 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs992497683, COSV99815853; called by muse, mutect2, varscan2
- DOP1A | c.6663C>A p.F2221L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99383134; called by muse, mutect2, varscan2
- DPP10 | c.1912C>A p.P638T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs142445583; called by muse, mutect2, varscan2
- DPPA5 | c.294G>A p.G98= | Splice Region (SNP) | VAF 85/160 reads (53%) | catalogued as COSV100951534; called by muse, mutect2, varscan2
- DROSHA | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.025); catalogued as COSV100757858; called by muse, mutect2, varscan2
- DSEL | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100026195; called by muse, mutect2, varscan2
- DSG2 | c.2905G>T p.A969S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV99853649; called by muse, mutect2, varscan2
- DUSP22 | c.21+1G>T p.X7_splice | Splice Site (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100740152; called by muse, mutect2, varscan2
- DUSP22 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 83/352 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768192099, COSV100740154, COSV60529218; called by muse, mutect2, varscan2
- DYDC1 | c.249+1G>C p.X83_splice | Splice Site (SNP) | VAF 24/113 reads (21%) | catalogued as COSV99758233; called by muse, mutect2, varscan2
- DYDC1 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99758234; called by muse, mutect2, varscan2
- DYM | c.1997T>C p.M666T | Missense Mutation (SNP) | VAF 150/318 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV99494419; called by muse, mutect2, varscan2
- DYSF | c.2895G>T p.W965C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99251091; called by muse, mutect2, varscan2
- EFCAB5 | c.3280C>T p.R1094C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs374387593, COSV100300944; called by muse, varscan2
- EIF6 | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV99864215; called by muse, mutect2, varscan2
- ELAVL1 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.619); catalogued as COSV100688548; called by muse, mutect2, varscan2
- EPHA3 | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60693678, COSV60700101; called by muse, mutect2, varscan2
- EPHA3 | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 94/137 reads (69%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV100349595; called by muse, mutect2, varscan2
- ESR1 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); catalogued as COSV99241774; called by muse, mutect2
- ESR2 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs1241458487, COSV99964032; called by muse, varscan2
- ESX1 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 109/132 reads (83%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as rs1159940362, COSV101006522; called by muse, mutect2, varscan2
- EXOC7 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 109/134 reads (81%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.886); catalogued as COSV100135909; called by muse, mutect2, varscan2
- EXT1 | c.1418-1G>T p.X473_splice | Splice Site (SNP) | VAF 45/124 reads (36%) | catalogued as CS065547, COSV100984130, COSV100984153; called by muse, mutect2, varscan2
- F13B | c.364T>C p.Y122H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1248042126, COSV100803532, COSV66374666; called by muse, mutect2
- FAM135A | c.2198G>T p.R733L (on ENST00000370479 / NM_001351599.1; = p.R520L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs143752744, COSV99526823; called by muse, mutect2, varscan2
- FAM135B | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.496); catalogued as rs1287261497, COSV50523423, COSV99358414; called by muse, mutect2, varscan2
- FAM237A | c.389C>G p.P130R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.239); catalogued as COSV101405607; called by muse, mutect2, varscan2
- FAT3 | c.10970C>A p.S3657Y | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53133364, COSV53184206; called by muse, mutect2, varscan2
- FBXL18 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs956442026, COSV101154755; called by muse, mutect2, varscan2
- FBXL18 | c.89G>C p.G30A | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.107); catalogued as rs113643930, COSV101212131; called by muse, mutect2, varscan2
- FHOD3 | c.1669G>T p.G557W (on ENST00000359247 / NM_001281739.3; = p.G574W on NM_025135.5) | Missense Mutation (SNP) | VAF 93/279 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.739); catalogued as rs746145023, COSV57169252; called by muse, mutect2, varscan2
- FLG | c.5152C>A p.Q1718K | Missense Mutation (SNP) | VAF 212/544 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100911684, COSV100912394; called by muse, mutect2, varscan2
- FLT3 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); catalogued as COSV99610481; called by muse, mutect2, varscan2
- FNDC1 | c.3692C>A p.A1231D | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV99797295; called by muse, varscan2
- FRYL | c.6169C>G p.P2057A | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.643); catalogued as COSV51956815, COSV99978492; called by muse, mutect2, varscan2
- FSIP2 | c.17514G>T p.E5838D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100553905, COSV100554592, COSV100556893; called by muse, mutect2, varscan2
- FTSJ3 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs370864062; called by muse, mutect2, varscan2
- FUT9 | c.1001C>A p.A334E | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as COSV100134645; called by muse, mutect2, varscan2
- FYCO1 | c.3571C>T p.R1191W | Missense Mutation (SNP) | VAF 89/134 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773967962, COSV56115240; called by muse, mutect2, varscan2
- FZD8 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.25); catalogued as COSV101020281; called by muse, mutect2, varscan2
- GALNT13 | c.1168G>C p.V390L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV101224396; called by muse, mutect2, varscan2
- GFM1 | c.1133T>C p.L378P | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99963250; called by muse, mutect2, varscan2
- GFM1 | c.1906C>A p.Q636K | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.068); catalogued as COSV99963253; called by muse, mutect2, varscan2
- GK2 | c.1354C>A p.P452T | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT tolerated (0.6); PolyPhen benign (0.261); catalogued as rs1239771243, COSV100726066; called by muse, mutect2, varscan2
- GLS | c.1465C>G p.L489V | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as rs899300977, COSV100290600; called by muse, mutect2, varscan2
- GPATCH8 | c.2776C>T p.H926Y | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.637); catalogued as COSV100132934; called by muse, mutect2, varscan2
- GPC5 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.062); catalogued as COSV100996315; called by muse, mutect2, varscan2
- GPRIN1 | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.33); catalogued as COSV99992286; called by muse, mutect2, varscan2
- GRAMD4 | c.928C>A p.Q310K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100730698; called by muse, mutect2, varscan2
- GRB10 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 40/90 reads (44%) | catalogued as COSV100241273; called by muse, mutect2, varscan2
- GREB1 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.053); catalogued as rs1352432555, COSV99304017; called by muse, mutect2, varscan2
- GRIK2 | c.2610G>T p.K870N | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as COSV100030074; called by muse, mutect2, varscan2
- GRIK4 | c.471C>G p.F157L | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.996); catalogued as COSV101483865; called by muse, mutect2, varscan2
- GRK1 | c.492G>C p.E164D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.071); catalogued as COSV100175492; called by muse, mutect2, varscan2
- GRM8 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100286786; called by muse, mutect2, varscan2
- GRXCR1 | c.319A>G p.R107G | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101295764; called by muse, mutect2, varscan2
- GUCA1C | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV99228129; called by muse, mutect2, varscan2
- H2AC1 | c.166T>A p.L56I | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.969); catalogued as COSV99219605; called by muse, mutect2, varscan2
- HECW1 | c.1825G>T p.D609Y | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); catalogued as COSV101224402; called by muse, mutect2, varscan2
- HNF4G | c.967G>A p.E323K (on ENST00000354370 / NM_001330561.2; = p.E370K on NM_004133.5) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV62967143; called by muse, mutect2, varscan2
- HTR1D | c.335A>T p.D112V | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100025109; called by muse, mutect2, varscan2
- ICAM2 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99857064; called by muse, mutect2, varscan2
- IGF2R | c.4951G>T p.E1651* | Nonsense Mutation (SNP) | VAF 33/48 reads (69%) | catalogued as COSV100808364; called by muse, mutect2, varscan2
- IGFBP7 | c.537G>T p.L179F | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99825741; called by muse, mutect2, varscan2
- IGHD6-25 | c.10A>T p.S4C | Missense Mutation (SNP) | VAF 98/131 reads (75%) | catalogued as rs537980944; called by muse, mutect2
- IGHMBP2 | c.1274G>T p.R425L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99662537, COSV99662681; called by muse, varscan2
- IGHV3-30 | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 35/494 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.208); catalogued as rs3764180; called by muse, mutect2
- IGKV1-6 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 133/272 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs752300089; called by muse, mutect2, varscan2
- IGKV1D-42 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs749575888; called by muse, mutect2, varscan2
- IL13RA2 | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT tolerated (0.45); PolyPhen benign (0.242); catalogued as COSV99683437; called by muse, mutect2, varscan2
- INMT | c.661G>T p.V221L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as COSV99185180; called by muse, mutect2, varscan2
- ISM2 | c.372C>A p.N124K | Missense Mutation (SNP) | VAF 62/98 reads (63%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.792); catalogued as COSV99376958; called by muse, mutect2, varscan2
- JPH2 | c.736G>T p.V246F | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0.155); catalogued as rs1326771127, COSV100881805; called by muse, mutect2
- JPH4 | c.1402C>G p.R468G | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.088); catalogued as COSV100437090; called by muse, mutect2, varscan2
- KCNA1 | c.1204C>A p.L402M | Missense Mutation (SNP) | VAF 234/697 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101230403, COSV101230405; called by muse, mutect2, varscan2
- KCNAB1 | c.358G>A p.V120I (on ENST00000490337 / NM_172160.3; = p.V109I on NM_003471.3) | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV100205293; called by muse, mutect2, varscan2
- KCNJ10 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100927967; called by muse, mutect2, varscan2
- KDM4D | c.437A>T p.D146V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100624393; called by muse, mutect2, varscan2
- KIF1A | c.4923G>T p.Q1641H (on ENST00000320389 / NM_001379639.1; = p.Q1633H on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV100242686; called by muse, mutect2, varscan2
- KIF25 | c.1027A>C p.S343R (on ENST00000354419 / NM_030615.2; = p.S291R on NM_005355.3) | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.222); catalogued as COSV100596302, COSV100596529; called by muse, mutect2, varscan2
- KIFC2 | c.448G>T p.V150F | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV100024038; called by muse, mutect2, varscan2
- KLK15 | c.161C>G p.P54R | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV100033090; called by muse, varscan2
- KSR1 | c.1702G>T p.G568C (on ENST00000644974 / NM_001367810.1; = p.G453C on NM_014238.2) | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV99261126; called by muse, mutect2, varscan2
- LCOR | c.4273G>C p.A1425P | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99617272; called by muse, mutect2, varscan2
- LDB3 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99555413; called by muse, mutect2, varscan2
- LDB3 | c.1880A>G p.Q627R | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99556048; called by muse, mutect2, varscan2
- LRFN1 | c.840C>A p.H280Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV99953474; called by muse, mutect2, varscan2
- LRP1B | c.10057+1G>T p.X3353_splice | Splice Site (SNP) | VAF 30/67 reads (45%) | catalogued as COSV101262155, COSV67230649; called by muse, mutect2, varscan2
- LRP1B | c.6990-1G>A p.X2330_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as COSV101262156, COSV67232715; called by muse, mutect2, varscan2
- LRRC4 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as COSV99975289; called by muse, mutect2, varscan2
- LRRC43 | c.1124T>C p.V375A | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100337033; called by muse, mutect2, varscan2
- LRRC7 | c.422-2A>T p.X141_splice (on ENST00000651989 / NM_001370785.2; = p.X108_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV50644867; called by muse, mutect2
- LRRC75B | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 50/491 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs774605663, COSV50643430, COSV99959431; called by muse, mutect2, varscan2
- LRRIQ4 | c.1540T>C p.W514R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99247215; called by muse, mutect2
- LRRTM3 | c.663C>A p.N221K | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100791965; called by muse, mutect2, varscan2
- LRTM2 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 87/173 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99765291, COSV99766766; called by muse, mutect2, varscan2
- MAP7 | c.1611G>T p.E537D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV100644062; called by muse, mutect2
- MAPK4 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV101246084, COSV68541044; called by muse, mutect2, varscan2
- MC4R | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as CM035774, COSV100236168; called by muse, mutect2, varscan2
- MCF2L2 | c.1063C>G p.H355D | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV100194211; called by muse, mutect2, varscan2
- MDGA2 | c.2060G>T p.G687V (on ENST00000399232 / NM_001113498.2; = p.G389V on NM_182830.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100638820; called by muse, mutect2, varscan2
- MDGA2 | c.1473G>T p.K491N (on ENST00000399232 / NM_001113498.2; = p.K193N on NM_182830.4) | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV100638821; called by muse, mutect2, varscan2
- MERTK | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs751150587, COSV54928652; called by muse, mutect2, varscan2
- MGA | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99581986; called by muse, mutect2, varscan2
- MINPP1 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV64355043; called by muse, mutect2, varscan2
- MIPEP | c.1837G>T p.V613F | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101193290; called by muse, mutect2
- MKNK1 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1417769153, COSV100361579; called by muse, mutect2, varscan2
- MMP2 | c.1451A>G p.E484G | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99528376; called by muse, mutect2, varscan2
- MORC1 | c.216G>T p.M72I | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1306109726, COSV51726713, COSV99228132; called by muse, mutect2, varscan2
- MOSPD3 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.681); catalogued as COSV99775047; called by muse, mutect2, varscan2
- MOXD1 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 67/106 reads (63%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100382040; called by muse, mutect2, varscan2
- MS4A4A | c.511T>G p.S171A | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.038); catalogued as COSV100557746, COSV100557975; called by muse, mutect2, varscan2
- MS4A6A | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs1440597159, COSV100125153; called by muse, mutect2
- MTIF2 | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 17/32 reads (53%) | catalogued as COSV99703300; called by muse, mutect2, varscan2
- MTX1 | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100366992; called by muse, mutect2, varscan2
- MUC16 | c.36398C>A p.P12133Q | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV101202135, COSV67501649; called by muse, mutect2, varscan2
- MUC16 | c.16079C>A p.S5360Y | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV101202137, COSV67500091; called by muse, mutect2, varscan2
- MUC16 | c.13694C>A p.T4565K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV101202138; called by muse, mutect2, varscan2
- MUC16 | c.10772C>A p.S3591Y | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV67488870, COSV67492576; called by muse, mutect2, varscan2
- MUC16 | c.10454C>G p.A3485G | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); catalogued as rs200594255, COSV101202141, COSV67476944; called by muse, mutect2, varscan2
- MUC5B | c.4543G>A p.E1515K | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.844); catalogued as COSV71592015; called by muse, mutect2, varscan2
- MUC5B | c.16255G>C p.G5419R | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV101500921; called by muse, mutect2, varscan2
- MYH1 | c.593C>A p.T198K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99877159; called by muse, mutect2, varscan2
- MYH14 | c.4742G>A p.R1581H | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs750628523, COSV51813890, COSV51828784; called by muse, mutect2, varscan2
- MYH15 | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99844537; called by muse, mutect2, varscan2
- MYH2 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as COSV99821170; called by muse, mutect2, varscan2
- MYLK3 | c.1797C>A p.D599E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV101189250; called by muse, mutect2, varscan2
- MYO16 | c.202A>T p.I68F | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99194934; called by muse, mutect2, varscan2
- MYT1L | c.2395C>T p.Q799* | Nonsense Mutation (SNP) | VAF 50/153 reads (33%) | catalogued as COSV101221568; called by muse, mutect2, varscan2
- NALCN | c.2936A>T p.E979V | Missense Mutation (SNP) | VAF 73/95 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV99218447; called by muse, mutect2, varscan2
- NAV3 | c.2405G>C p.S802T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs558608455, COSV99896715; called by muse, mutect2, varscan2
- NCAN | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99388583; called by muse, mutect2, varscan2
- NEURL3 | c.631A>T p.N211Y | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100182536; called by muse, mutect2, varscan2
- NIT2 | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV101237143, COSV67630391; called by muse, mutect2, varscan2
- NLRP12 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100146064; called by muse, mutect2, varscan2
- NLRP4 | c.1797G>T p.L599F | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100017378; called by muse, mutect2, varscan2
- NOL11 | c.1531A>G p.I511V | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV53524786; called by muse, mutect2, varscan2
- NOTCH1 | c.6985A>T p.S2329C | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.235); catalogued as rs772040833, COSV53032526; called by muse, mutect2, varscan2
- NPAS4 | c.499G>C p.V167L | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV100215057, COSV100215345, COSV60650174; called by muse, mutect2, varscan2
- NPTX1 | c.445-1G>C p.X149_splice | Splice Site (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100151223, COSV60774416; called by muse, mutect2, varscan2
- NRAP | c.4373C>A p.T1458K (on ENST00000359988 / NM_001322945.2; = p.T1423K on NM_006175.4) | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.097); catalogued as COSV100748665; called by muse, mutect2, varscan2
- NSUN4 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100197714; called by muse, mutect2, varscan2
- NUTM1 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100412678; called by muse, mutect2, varscan2
- OAS2 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100660356; called by muse, mutect2, varscan2
- OR10G8 | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs141086209, COSV101461868, COSV101461894; called by muse, mutect2, varscan2
- OR1L8 | c.62G>C p.R21P | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as rs1344222880, COSV100508717, COSV59187538; called by muse, mutect2, varscan2
- OR2G2 | c.377A>T p.Y126F | Missense Mutation (SNP) | VAF 118/227 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.355); catalogued as COSV100190057, COSV60740347, COSV60742203; called by muse, mutect2, varscan2
- OR2H1 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 96/195 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101009955; called by muse, mutect2, varscan2
- OR2T11 | c.310A>G p.M104V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58186959; called by muse, mutect2, varscan2
- OR2T3 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100613360, COSV100613473; called by muse, mutect2, varscan2
- OR2T3 | c.942G>T p.M314I | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs552029313, COSV100613474, COSV62081866; called by muse, mutect2, varscan2
- OR2T34 | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV100170595; called by muse, mutect2, varscan2
- OR4N2 | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs1272497194, COSV100270099; called by muse, varscan2
- OR51I2 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100413507; called by muse, mutect2, varscan2
- OR51S1 | c.826A>T p.T276S | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV100437607; called by muse, mutect2, varscan2
- OR52A1 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61092444; called by muse, mutect2, varscan2
- OR52B4 | c.807C>G p.H269Q | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV101281618; called by muse, mutect2, varscan2
- OR52B4 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs200795232; called by muse, mutect2, varscan2
- OR52K1 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV100297759; called by muse, varscan2
- OR52K1 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.559); catalogued as COSV100297760; called by muse, varscan2
- OR52K2 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.661); catalogued as COSV100355855, COSV57835878; called by muse, mutect2, varscan2
- OR5B12 | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV100222604; called by muse, mutect2, varscan2
- OR6S1 | c.746T>C p.I249T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100289581, COSV57837465; called by muse, mutect2, varscan2
- PAG1 | c.1293G>T p.R431S | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99597478, COSV99598001; called by muse, mutect2, varscan2
- PAH | c.889C>A p.R297S | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as CM961079, COSV100188508, COSV61015366; called by muse, mutect2, varscan2
- PAN3 | c.2663A>T p.*888Lext*11 | Nonstop Mutation (SNP) | VAF 24/44 reads (55%) | catalogued as COSV99145291; called by muse, mutect2, varscan2
- PAX6 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as rs374396492, CM068271, COSV53795898; called by muse, mutect2, varscan2
- PCDH15 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.842); catalogued as rs752256957, COSV57340947, COSV57387588; called by muse, mutect2, varscan2
- PCDHB3 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 56/81 reads (69%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.018); catalogued as COSV50634280, COSV99167037; called by muse, mutect2, varscan2
- PCDHGA5 | c.2113C>A p.L705M | Missense Mutation (SNP) | VAF 210/317 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99549070; called by muse, mutect2, varscan2
- PCNX4 | c.362G>T p.C121F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100470989; called by muse, mutect2, varscan2
- PDE10A | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63094901; called by muse, mutect2
- PDE1B | c.1462C>A p.R488S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99226560; called by muse, mutect2, varscan2
- PDGFRA | c.2764A>G p.T922A | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as COSV99957959; called by muse, mutect2, varscan2
- PEG3 | c.673G>C p.A225P | Missense Mutation (SNP) | VAF 78/138 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV99690822; called by muse, mutect2, varscan2
- PFKL | c.1763G>T p.G588V | Missense Mutation (SNP) | VAF 54/77 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751862472, COSV60363869; called by muse, mutect2, varscan2
- PGPEP1L | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 88/176 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs761032396, COSV100967265; called by muse, mutect2, varscan2
- PHOX2A | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99996758; called by muse, mutect2, varscan2
- PLAT | c.741G>T p.K247N | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV99534897; called by muse, mutect2, varscan2
- PLXNA2 | c.2002A>G p.S668G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV100886150; called by muse, mutect2, varscan2
- PPP4R4 | c.1520T>A p.L507H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100429121; called by muse, mutect2, varscan2
- PRDM9 | c.2249G>A p.C750Y | Missense Mutation (SNP) | VAF 133/287 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99691492; called by muse, varscan2
- PRSS35 | c.461G>T p.C154F | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100864169; called by muse, mutect2, varscan2
- PSME4 | c.2791G>T p.G931W | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101122734; called by muse, mutect2, varscan2
- PTPRC | c.2372A>G p.D791G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760021216, COSV100723315; called by muse, mutect2, varscan2
- PXDNL | c.3028C>T p.Q1010* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as COSV100687042; called by muse, mutect2, varscan2
- R3HDM1 | c.752A>C p.Q251P | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV99927000; called by muse, mutect2, varscan2
- RASAL3 | c.120G>T p.W40C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99484365; called by muse, mutect2, varscan2
- RBAK | c.1460G>C p.C487S | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100806801; called by muse, mutect2, varscan2
- RBL1 | c.534G>T p.W178C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60333696; called by muse, mutect2, varscan2
- REG3A | c.329C>A p.T110K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as COSV100532811; called by muse, mutect2, varscan2
- REG3G | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV55449230; called by muse, mutect2, varscan2
- ROBO3 | c.3428C>G p.S1143C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100127848, COSV100127915, COSV60621453; called by muse, mutect2, varscan2
- ROS1 | c.3059C>G p.P1020R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100877845, COSV63862424; called by mutect2, varscan2
- RUNX1T1 | c.764G>T p.R255I (on ENST00000265814 / NM_001198628.1; = p.R228I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV99755734; called by muse, mutect2, varscan2
- RXRG | c.648C>A p.S216R | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV100717935; called by muse, mutect2, varscan2
- SACS | c.8321G>A p.R2774K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.438); catalogued as COSV101207846; called by muse, mutect2, varscan2
- SATB2 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.795); catalogued as COSV99613012; called by muse, mutect2, varscan2
- SAYSD1 | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100010290; called by muse, mutect2, varscan2
- SBSN | c.1425A>T p.K475N (on ENST00000452271 / NM_001166034.2; = p.K132N on NM_198538.4) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV101510121; called by muse, mutect2, varscan2
- SCAF11 | c.2155A>G p.M719V | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs774899627, COSV101014742; called by muse, mutect2, varscan2
- SCAF8 | c.1448A>T p.Q483L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100914322; called by muse, mutect2, varscan2
- SCN10A | c.2202C>A p.C734* | Nonsense Mutation (SNP) | VAF 39/55 reads (71%) | catalogued as COSV101479579; called by muse, mutect2, varscan2
- SEMA4D | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV100358935; called by muse, mutect2, varscan2
- SERPINB6 | c.1094_1095insG p.R367Pfs*46 (on ENST00000612421 / NM_001271823.2; = p.R348Pfs*46 on NM_004568.6) | Frame Shift Ins (INS) | VAF 19/73 reads (26%) | catalogued as COSV100177758; called by mutect2, pindel, varscan2
- SF3B1 | c.3094C>T p.Q1032* | Nonsense Mutation (SNP) | VAF 43/137 reads (31%) | catalogued as COSV100136085; called by muse, mutect2, varscan2
- SFXN5 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as rs770902510, COSV55588310; called by muse, mutect2, varscan2
- SHANK1 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV104394991, COSV99522263; called by muse, mutect2, varscan2
- SI | c.3323C>G p.S1108* | Nonsense Mutation (SNP) | VAF 67/161 reads (42%) | catalogued as COSV100017524, COSV52264546; called by muse, mutect2, varscan2
- SLAMF7 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as rs759179645, COSV100833391; called by muse, mutect2, varscan2
- SLC26A1 | c.1280T>A p.L427Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99926571; called by muse, mutect2, varscan2
- SLC27A6 | c.407A>T p.N136I | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99323664; called by muse, mutect2, varscan2
- SLC7A14 | c.1718T>G p.F573C | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99201149; called by muse, mutect2, varscan2
- SMAD2 | c.1262G>C p.G421A | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100054156; called by muse, mutect2, varscan2
- SMUG1 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99679573; called by muse, mutect2, varscan2
- SMUG1 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99679575; called by muse, mutect2, varscan2
- SOX13 | c.520A>T p.K174* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV99690087; called by muse, mutect2, varscan2
- SPHKAP | c.1273G>T p.G425* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | catalogued as COSV60892358; called by muse, mutect2, varscan2
- SPN | c.431G>T p.S144I | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV100788923; called by muse, mutect2, varscan2
- SRCAP | c.8152C>T p.R2718* | Nonsense Mutation (SNP) | VAF 41/83 reads (49%) | catalogued as COSV99351631; called by muse, mutect2, varscan2
- STK4 | c.1275G>T p.W425C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); catalogued as COSV100860526; called by muse, mutect2, varscan2
- SUPT6H | c.2908G>C p.G970R | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100112883; called by muse, mutect2, varscan2
- TAAR9 | c.519C>A p.N173K | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs372695882, COSV71512268; called by muse, mutect2, varscan2
- TAF2 | c.2401G>T p.A801S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV100978841; called by muse, mutect2, varscan2
- TAGLN | c.403A>T p.S135C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV99639260; called by muse, mutect2, varscan2
- TAP2 | c.740-1G>T p.X247_splice | Splice Site (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100886973; called by muse, mutect2, varscan2
- TBX5 | c.479T>A p.L160H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100092429; called by muse, mutect2, varscan2
- TECPR2 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs770891850, COSV63971890; called by muse, mutect2, varscan2
- TEP1 | c.3563C>T p.P1188L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV53001540, COSV99403525; called by muse, mutect2, varscan2
- TFPI | c.537G>T p.P179= | Splice Region (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99258978, COSV99259963; called by muse, mutect2
- THAP4 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV101126117; called by muse, mutect2, varscan2
- TIMD4 | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV99192987; called by muse, mutect2, varscan2
- TLR4 | c.1636C>A p.L546I (on ENST00000355622 / NM_138554.5; = p.L506I on NM_003266.4) | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100842758, COSV62923168; called by muse, mutect2, varscan2
- TLR4 | c.1849G>T p.G617C (on ENST00000355622 / NM_138554.5; = p.G577C on NM_003266.4) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100842906; called by muse, mutect2, varscan2
- TM4SF19 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99879477; called by muse, mutect2
- TMEM151A | c.925G>C p.A309P | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100517096; called by muse, mutect2, varscan2
- TMEM31 | c.251C>G p.P84R | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV100129135; called by muse, mutect2, varscan2
- TMPRSS15 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53039559; called by muse, mutect2, varscan2
- TMPRSS7 | c.1181G>T p.C394F (on ENST00000452346; = p.C268F on NM_001042575.2) | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101340195; called by muse, mutect2, varscan2
- TNIK | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV99460269; called by muse, mutect2, varscan2
- TNR | c.540C>G p.N180K | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99692112; called by muse, mutect2, varscan2
- TPH2 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61590829, COSV61591310, COSV61591702; called by muse, mutect2, varscan2
- TRAK2 | c.1763G>C p.R588P | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100216704, COSV100217224; called by muse, mutect2, varscan2
- TRBC2 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs576818678; called by muse, mutect2, varscan2
- TRHDE | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99673063; called by muse, mutect2, varscan2
- TRPM1 | c.1133C>A p.A378E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99856896; called by muse, mutect2, varscan2
- TRPS1 | c.2191C>T p.H731Y (on ENST00000220888 / NM_001330599.2; = p.H744Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.013); catalogued as COSV55246185, COSV99635315; called by muse, mutect2, varscan2
- TRRAP | c.8066G>A p.R2689Q (on ENST00000359863 / NM_001244580.1; = p.R2671Q on NM_003496.3) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as COSV100723186; called by muse, mutect2, varscan2
- TSHB | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 79/148 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV99858981, COSV99859151; called by muse, mutect2, varscan2
- TTI2 | c.166G>C p.G56R | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated (0.63); PolyPhen benign (0.258); catalogued as COSV100659851, COSV62452216; called by muse, mutect2, varscan2
- TTN | c.83657G>T p.R27886I (on ENST00000591111; = p.R20462I on NM_003319.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | PolyPhen possibly damaging (0.777); catalogued as COSV100634760; called by muse, mutect2, varscan2
- TTN | c.71141A>T p.H23714L (on ENST00000591111; = p.H16290L on NM_003319.4) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | PolyPhen benign (0.107); catalogued as COSV100634763; called by muse, mutect2, varscan2
- TTN | c.52564C>A p.L17522I (on ENST00000591111; = p.L10098I on NM_003319.4) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | PolyPhen probably damaging (0.996); catalogued as COSV100634765; called by muse, mutect2, varscan2
- TTN | c.8373C>A p.H2791Q (on ENST00000591111; = p.H2745Q on NM_003319.4) | Missense Mutation (SNP) | VAF 34/68 reads (50%) | PolyPhen possibly damaging (0.865); catalogued as rs566816279, COSV100634770, COSV59938234, COSV60187390; called by muse, mutect2, varscan2
- TTR | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | catalogued as CM930708, COSV99379653; called by muse, mutect2, varscan2
- TUBA3C | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 84/113 reads (74%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); catalogued as rs1226855350, COSV67139322, COSV67139843; called by muse, mutect2, varscan2
- TYK2 | c.3391G>T p.G1131W | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99315602; called by muse, varscan2
- UBE2M | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs945745478, COSV99285507; called by muse, mutect2, varscan2
- UBP1 | c.663C>A p.Y221* | Nonsense Mutation (SNP) | VAF 60/92 reads (65%) | catalogued as COSV99372970; called by muse, mutect2, varscan2
- UBQLN3 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100294028; called by muse, mutect2, varscan2
- UBXN2A | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 53/121 reads (44%) | catalogued as COSV100465366; called by muse, mutect2, varscan2
- UNC13C | c.5215C>A p.Q1739K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV52888579, COSV99524096; called by muse, mutect2, varscan2
- USP25 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 66/98 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.258); catalogued as COSV99584796; called by muse, mutect2, varscan2
- USP34 | c.1888G>T p.G630C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.159); catalogued as rs763566645, COSV101277294; called by muse, mutect2, varscan2
- UVRAG | c.563G>C p.R188P | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100638711, COSV62109875; called by muse, mutect2, varscan2
- VCAM1 | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.664); catalogued as rs544572881, COSV99659020; called by muse, mutect2, varscan2
- VGF | c.476T>A p.L159Q | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99973264; called by muse, mutect2, varscan2
- VPS13C | c.2470G>C p.D824H (on ENST00000644861 / NM_020821.3; = p.D781H on NM_017684.5) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV99830606; called by muse, mutect2, varscan2
- XPO1 | c.2194A>C p.I732L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV101294333; called by muse, mutect2, varscan2
- ZDHHC8 | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100273313; called by muse, mutect2
- ZEB1 | c.3065C>A p.S1022* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV58036938, COSV58047866; called by muse, mutect2, varscan2
- ZEB2 | c.2062G>C p.V688L | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV100357184; called by muse, mutect2, varscan2
- ZFAND4 | c.1702A>T p.S568C | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV100763144; called by muse, mutect2, varscan2
- ZFHX4 | c.3021C>A p.Y1007* | Nonsense Mutation (SNP) | VAF 44/128 reads (34%) | catalogued as COSV99268913; called by muse, mutect2, varscan2
- ZFPM2 | c.1713C>A p.C571* | Nonsense Mutation (SNP) | VAF 94/266 reads (35%) | catalogued as COSV101023693, COSV65876029; called by muse, mutect2, varscan2
- ZFR | c.2194G>T p.A732S | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV99416711; called by muse, mutect2, varscan2
- ZIC3 | c.1301C>A p.A434D | Missense Mutation (SNP) | VAF 159/193 reads (82%) | SIFT tolerated (0.64); PolyPhen benign (0.296); catalogued as COSV99798532, COSV99799639; called by muse, mutect2, varscan2
- ZIM3 | c.141G>T p.V47= | Splice Region (SNP) | VAF 42/107 reads (39%) | catalogued as COSV54144513, COSV99518848; called by muse, mutect2, varscan2
- ZNF100 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV99974415; called by muse, mutect2, varscan2
- ZNF106 | c.494A>C p.K165T | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV99783321; called by muse, mutect2, varscan2
- ZNF133 | c.1330G>T p.G444W (on ENST00000316358 / NM_001352454.2; = p.G443W on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100315696; called by muse, mutect2, varscan2
- ZNF2 | c.1112A>T p.Q371L (on ENST00000611147 / NM_001291605.2; = p.Q358L on NM_021088.4) | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99728762; called by muse, mutect2, varscan2
- ZNF236 | c.482A>C p.E161A | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.371); catalogued as COSV99471458; called by muse, mutect2
- ZNF236 | c.483G>T p.E161D | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.371); catalogued as COSV99471462; called by muse, mutect2
- ZNF382 | c.1381del p.E461Kfs*84 | Frame Shift Del (DEL) | VAF 40/115 reads (35%) | catalogued as COSV53086628, COSV53090943; called by mutect2, pindel, varscan2
- ZNF410 | c.677G>T p.C226F | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100206649; called by muse, mutect2, varscan2
- ZNF496 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); catalogued as COSV99666348; called by muse, mutect2, varscan2
- ZNF574 | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 83/347 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.072); catalogued as COSV99726624; called by muse, mutect2, varscan2
- ZSWIM3 | c.1069G>T p.V357L | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54845151, COSV99667083; called by muse, mutect2, varscan2
- ANAPC1 | c.3206G>T p.R1069I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ATP1B4 | c.899del p.G300Afs*3 (on ENST00000218008 / NM_001142447.3; = p.G296Afs*3 on NM_012069.5) | Frame Shift Del (DEL) | VAF 92/146 reads (63%) | called by mutect2, pindel, varscan2
- AZU1 | c.155_156insA p.C52* | Nonsense Mutation (INS) | VAF 50/126 reads (40%) | called by mutect2, pindel*, varscan2
- CAMSAP3 | c.303_328del p.S102Efs*32 | Frame Shift Del (DEL) | VAF 27/145 reads (19%) | called by mutect2, pindel
- CNTNAP3 | c.3172G>T p.V1058L | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CYFIP1 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- DNAH8 | c.2130+4_2130+12del p.X710_splice | Splice Site (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- ENDOU | c.496del p.Q166Kfs*70 (on ENST00000422538 / NM_001172439.2; = p.Q125Kfs*70 on NM_006025.4) | Frame Shift Del (DEL) | VAF 28/190 reads (15%) | called by mutect2, varscan2
- ENDOU | c.495C>A p.S165R (on ENST00000422538 / NM_001172439.2; = p.S124R on NM_006025.4) | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- FBXO21 | c.1310dup p.I438Nfs*15 (on ENST00000330622 / NM_033624.3; = p.I438Nfs*8 on NM_015002.3) | Frame Shift Ins (INS) | VAF 37/149 reads (25%) | called by mutect2, pindel, varscan2
- FRG2 | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRG2C | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2
- GABRB1 | c.1231del p.R411Afs*33 | Frame Shift Del (DEL) | VAF 30/107 reads (28%) | called by mutect2, pindel, varscan2
- GDAP2 | c.1303_1305del p.V435del | In Frame Del (DEL) | VAF 36/57 reads (63%) | called by mutect2, pindel, varscan2
- KIF21A | c.4971dup p.D1658Rfs*6 (on ENST00000361418 / NM_001378440.1; = p.D1645Rfs*6 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 25/77 reads (32%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 201/404 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MS4A6E | c.243_250del p.S82Vfs*2 | Frame Shift Del (DEL) | VAF 27/124 reads (22%) | called by mutect2, pindel, varscan2
- NMD3 | c.1030del p.E344Kfs*10 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- NT5E | c.1225del p.E409Rfs*15 | Frame Shift Del (DEL) | VAF 38/93 reads (41%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.7064del p.N2355Tfs*2 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | called by mutect2, varscan2
- RYR3 | c.4098dup p.V1367Sfs*8 | Frame Shift Ins (INS) | VAF 45/157 reads (29%) | called by mutect2, pindel, varscan2
- SLC26A1 | c.100dup p.R34Kfs*114 | Frame Shift Ins (INS) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- TENM3 | c.7776G>T p.R2592S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- TUBA3E | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- TYK2 | c.3411del p.D1138Tfs*11 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | called by pindel, varscan2
- WASHC2A | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 70/195 reads (36%) | called by muse, mutect2, varscan2
- WIZ | c.4333del p.A1445Hfs*6 (on ENST00000673675 / NM_001371589.1; = p.A350Hfs*6 on NM_021241.3) | Frame Shift Del (DEL) | VAF 23/89 reads (26%) | called by mutect2, pindel, varscan2
- YY1AP1 | c.679del p.L227Cfs*7 (on ENST00000295566 / NM_139118.2; = p.L150Cfs*7 on NM_018253.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/109 reads (24%) | called by mutect2, pindel, varscan2
- ZBTB45 | c.578del p.P193Lfs*130 | Frame Shift Del (DEL) | VAF 44/326 reads (13%) | called by mutect2, pindel, varscan2
- ZKSCAN5 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.187); called by muse, mutect2
- ABCA8 | c.1437C>T p.A479= | Silent (SNP) | VAF 112/145 reads (77%) | catalogued as rs1405507216, COSV99287166; called by muse, mutect2, varscan2
- ABCB1 | c.1416G>T p.V472= | Silent (SNP) | VAF 58/141 reads (41%) | catalogued as COSV99712000, COSV99714757; called by muse, mutect2, varscan2
- ACSS3 | c.789T>G p.V263= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV99699612; called by muse, mutect2, varscan2
- AGBL1 | c.822C>T p.P274= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV101408291; called by muse, mutect2, varscan2
- AHSG | c.9C>A p.S3= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV99890094, COSV99890482; called by muse, mutect2, varscan2
- AMPH | c.765C>A p.L255= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as COSV100344021; called by muse, mutect2, varscan2
- ANGPTL4 | c.261C>A p.T87= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV100035305; called by muse, varscan2
- ANKRD34B | c.396G>A p.E132= | Silent (SNP) | VAF 71/103 reads (69%) | catalogued as COSV100103679; called by muse, mutect2, varscan2
- ASPH | c.1920C>A p.A640= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV101064577; called by muse, mutect2, varscan2
- ATP1A2 | c.210G>A p.L70= | Silent (SNP) | VAF 76/163 reads (47%) | catalogued as COSV100768218; called by muse, mutect2, varscan2
- B2M | c.129G>A p.L43= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV100837628; called by muse, mutect2, varscan2
- C1QC | c.699T>C p.S233= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as rs1385984352, COSV101009566; called by muse, mutect2, varscan2
- CACNA1E | c.3171G>T p.T1057= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs537667743, COSV100705803; called by muse, mutect2, varscan2
- CCKAR | c.288G>T p.P96= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV99810618; called by muse, mutect2, varscan2
- CD207 | c.870G>T p.G290= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV101338604; called by muse, varscan2
- CDK7 | c.633T>C p.P211= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV99841953; called by muse, mutect2, varscan2
- CERCAM | c.1596G>T p.L532= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as COSV100864134, COSV100864166; called by muse, varscan2
- CLDN6 | c.177C>A p.T59= | Silent (SNP) | VAF 51/98 reads (52%) | catalogued as COSV100172421, COSV58509141; called by muse, mutect2, varscan2
- CNR1 | c.921C>A p.R307= | Silent (SNP) | VAF 41/67 reads (61%) | catalogued as COSV100759374; called by muse, mutect2, varscan2
- CRB2 | c.2556C>A p.P852= | Silent (SNP) | VAF 58/87 reads (67%) | catalogued as rs750110353, COSV100749766; called by muse, mutect2, varscan2
- CSMD2 | c.9711C>T p.S3237= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV53906413, COSV99596735; called by muse, mutect2, varscan2
- CSMD2 | c.3543C>G p.S1181= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV99596742; called by muse, mutect2, varscan2
- CUX2 | c.591G>C p.A197= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV99921028; called by muse, mutect2, varscan2
- CYP11B2 | c.513C>A p.A171= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV100011269, COSV100011462; called by muse, mutect2, varscan2
- DFFA | c.921G>A p.R307= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs747165023, COSV100986710; called by muse, mutect2, varscan2
- DNAAF5 | c.1998G>T p.A666= | Silent (SNP) | VAF 122/251 reads (49%) | catalogued as COSV52419720; called by muse, mutect2, varscan2
- DPEP2 | c.279C>A p.P93= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV99263258; called by muse, mutect2, varscan2
- DPY19L1 | c.1842A>G p.L614= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs185466334, COSV100205137; called by muse, mutect2, varscan2
- DSG1 | c.2430T>A p.S810= | Silent (SNP) | VAF 68/146 reads (47%) | catalogued as COSV99936703; called by muse, mutect2, varscan2
- DSG3 | c.2967C>A p.L989= | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as COSV99934872; called by muse, mutect2, varscan2
- ELSPBP1 | c.294G>T p.L98= | Silent (SNP) | VAF 64/143 reads (45%) | catalogued as COSV100353804; called by muse, mutect2, varscan2
- EP400 | c.9144G>T p.G3048= | Silent (SNP) | VAF 46/90 reads (51%) | catalogued as COSV100202550; called by muse, mutect2, varscan2
- EPYC | c.531T>C p.N177= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99664960; called by muse, mutect2
- ERICH6 | c.1116A>T p.S372= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV99902119; called by muse, mutect2, varscan2
- EXOC4 | c.24G>A p.G8= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as COSV99556128; called by muse, mutect2, varscan2
- FABP4 | c.201G>T p.L67= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as COSV99808670; called by muse, mutect2, varscan2
- FAM155A | c.1017G>C p.T339= | Silent (SNP) | VAF 46/63 reads (73%) | catalogued as COSV101026717, COSV101030874; called by muse, mutect2, varscan2
- FBN2 | c.6264A>G p.V2088= | Silent (SNP) | VAF 65/88 reads (74%) | catalogued as COSV99331372; called by muse, mutect2, varscan2
- FER1L6 | c.558C>T p.L186= | Silent (SNP) | VAF 65/157 reads (41%) | catalogued as COSV101206245; called by muse, mutect2, varscan2
- FLG2 | c.5562C>T p.T1854= | Silent (SNP) | VAF 125/345 reads (36%) | catalogued as COSV101166303; called by muse, mutect2, varscan2
- FOXB1 | c.12C>G p.P4= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs751979966, COSV68525916; called by muse, mutect2, varscan2
- GAB4 | c.387C>A p.T129= | Silent (SNP) | VAF 133/421 reads (32%) | catalogued as COSV101272120; called by muse, mutect2, varscan2
- GAD2 | c.1410T>C p.H470= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as COSV52169497, COSV99393685; called by muse, mutect2, varscan2
- GAL3ST3 | c.528C>A p.P176= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100361027; called by muse, mutect2, varscan2
- GGN | c.858C>T p.A286= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs755486620, COSV99287740; called by muse, mutect2, varscan2
- GNAT3 | c.85C>A p.R29= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs751707136, COSV101242424; called by muse, mutect2, varscan2
- GPR182 | c.669C>A p.T223= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100267821; called by muse, mutect2, varscan2
- HCN1 | c.1245A>G p.E415= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100302821; called by muse, mutect2, varscan2
- HDAC4 | c.957C>T p.A319= | Silent (SNP) | VAF 53/234 reads (23%) | catalogued as rs142131540; ClinVar: benign; called by muse, mutect2, varscan2
- HIC2 | c.1782C>T p.C594= | Silent (SNP) | VAF 21/171 reads (12%) | catalogued as rs759699909, COSV68042879; called by muse, mutect2, varscan2
- HTR2A | c.942C>T p.S314= | Silent (SNP) | VAF 37/44 reads (84%) | catalogued as COSV101096906; called by muse, mutect2, varscan2
- ICE2 | c.2748A>T p.P916= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV99831911; called by muse, mutect2, varscan2
- ITGAD | c.1722C>T p.S574= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as COSV101210626; called by muse, mutect2, varscan2
- KCNA10 | c.408C>A p.P136= | Silent (SNP) | VAF 46/81 reads (57%) | catalogued as COSV100871505; called by muse, mutect2, varscan2
- KCNH4 | c.1500T>A p.R500= | Silent (SNP) | VAF 40/60 reads (67%) | catalogued as COSV99238030; called by muse, mutect2, varscan2
- KCNJ10 | c.231C>T p.G77= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as COSV100927966; called by muse, mutect2, varscan2
- KCTD8 | c.831G>A p.E277= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100760234; called by muse, mutect2, varscan2
- KIF14 | c.4158G>A p.G1386= | Silent (SNP) | VAF 56/125 reads (45%) | catalogued as COSV100950632; called by muse, mutect2, varscan2
- L1CAM | c.687C>A p.V229= | Silent (SNP) | VAF 36/54 reads (67%) | catalogued as COSV100649075; called by muse, mutect2, varscan2
- LMX1A | c.453G>A p.E151= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as COSV99673398; called by muse, mutect2, varscan2
- LRFN1 | c.693C>T p.F231= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV50502938; called by muse, mutect2, varscan2
- LRRC61 | c.342G>A p.Q114= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs780528344, COSV99784794; called by muse, mutect2, varscan2
- MAML1 | c.2121C>T p.S707= | Silent (SNP) | VAF 80/133 reads (60%) | catalogued as COSV99483524; called by muse, mutect2, varscan2
- MAST1 | c.366C>A p.P122= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as COSV99263854; called by muse, mutect2, varscan2
- MATN4 | c.945C>T p.T315= (on ENST00000372754; = p.T274= on NM_003833.4) | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as rs745341703, COSV100637194, COSV61351727; called by muse, mutect2, varscan2
- MBD5 | c.2553G>A p.A851= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs559879867, COSV68696704; called by muse, mutect2, varscan2
- MCM5 | c.757C>T p.L253= | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as COSV99332083; called by muse, mutect2, varscan2
- MGAM | c.723C>T p.S241= | Silent (SNP) | VAF 45/81 reads (56%) | catalogued as COSV101516579; called by muse, mutect2, varscan2
- MGAM | c.3369C>A p.S1123= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as COSV101527792; called by muse, mutect2, varscan2
- MUC17 | c.12997C>A p.R4333= | Silent (SNP) | VAF 64/193 reads (33%) | catalogued as COSV100075525, COSV60285161; called by muse, mutect2, varscan2
- NALCN | c.171G>T p.T57= | Silent (SNP) | VAF 55/68 reads (81%) | catalogued as COSV99218448; called by muse, mutect2, varscan2
- NCAPD3 | c.372A>G p.L124= | Silent (SNP) | VAF 586/627 reads (93%) | catalogued as rs1243006245, COSV101592973; called by muse, mutect2, varscan2
- NECTIN2 | c.315C>T p.F105= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs776686957, COSV52976864; called by mutect2, varscan2
- NPBWR2 | c.222C>A p.P74= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100871140; called by muse, mutect2, varscan2
- OR10Z1 | c.264G>T p.G88= | Silent (SNP) | VAF 65/262 reads (25%) | catalogued as rs1384111125, COSV63524735; called by muse, mutect2, varscan2
- OR2M7 | c.309C>T p.F103= | Silent (SNP) | VAF 69/322 reads (21%) | catalogued as COSV100522751; called by muse, mutect2, varscan2
- OR51V1 | c.123G>T p.V41= | Silent (SNP) | VAF 39/146 reads (27%) | catalogued as COSV100343558; called by muse, mutect2, varscan2
- OR56A4 | c.45C>A p.G15= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV100417734, COSV58111062; called by muse, mutect2, varscan2
- OR5H1 | c.420G>A p.L140= | Silent (SNP) | VAF 66/206 reads (32%) | catalogued as rs1440596390, COSV100641800; called by muse, varscan2
- OR6F1 | c.756T>C p.Y252= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100129517; called by muse, mutect2, varscan2
- OR7E24 | c.1011T>C p.Y337= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV101509695; called by muse, mutect2, varscan2
- OR8H3 | c.627G>T p.V209= | Silent (SNP) | VAF 73/176 reads (41%) | catalogued as COSV100539185; called by muse, mutect2, varscan2
- PCDH1 | c.3138A>C p.L1046= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV99747170; called by muse, varscan2
- PLCE1 | c.3618C>T p.F1206= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs1416007601, COSV99597711; called by muse, mutect2, varscan2
- PLEKHG4B | c.3393C>T p.V1131= (on ENST00000283426; = p.V1487= on NM_052909.5) | Silent (SNP) | VAF 54/189 reads (29%) | catalogued as COSV99361291; called by muse, mutect2, varscan2
- PSG8 | c.1206C>A p.G402= | Silent (SNP) | VAF 188/817 reads (23%) | catalogued as rs1255301940, COSV100126737; called by muse, mutect2, varscan2
- RPH3AL | c.303G>T p.V101= | Silent (SNP) | VAF 46/62 reads (74%) | catalogued as COSV100048096; called by muse, mutect2, varscan2
- RPTN | c.372G>A p.R124= | Silent (SNP) | VAF 137/353 reads (39%) | catalogued as COSV100285887; called by muse, mutect2, varscan2
- RUBCNL | c.1419C>A p.A473= | Silent (SNP) | VAF 12/13 reads (92%) | catalogued as COSV100529448; called by muse, mutect2, varscan2
- RXFP3 | c.639G>T p.S213= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs200520186, COSV57505994; called by muse, mutect2, varscan2
- RYR1 | c.9157C>A p.R3053= | Silent (SNP) | VAF 98/198 reads (49%) | catalogued as COSV100617287; called by muse, mutect2, varscan2
- RYR2 | c.2568C>T p.S856= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs267598434, COSV63664482, COSV63678432; called by muse, mutect2, varscan2
- RYR3 | c.4545G>T p.V1515= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV101215118, COSV66807898; called by muse, mutect2, varscan2
- SAMSN1 | c.1026C>A p.I342= | Silent (SNP) | VAF 39/58 reads (67%) | catalogued as COSV99582656; called by muse, mutect2, varscan2
- SAYSD1 | c.292C>T p.L98= | Silent (SNP) | VAF 82/163 reads (50%) | catalogued as COSV100010291; called by muse, mutect2, varscan2
- SCTR | c.1104C>A p.I368= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV99191779; called by muse, mutect2, varscan2
- SIGLEC1 | c.3672G>A p.L1224= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as COSV99171471; called by muse, mutect2, varscan2
- SIGLEC9 | c.666G>T p.V222= | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as COSV99143631; called by muse, mutect2, varscan2
- SLC12A2 | c.3207G>T p.R1069= | Silent (SNP) | VAF 53/71 reads (75%) | catalogued as COSV99320891; called by muse, mutect2, varscan2
- SLC6A11 | c.940C>T p.L314= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV99595151; called by muse, mutect2, varscan2
- SLC8A2 | c.2250C>A p.A750= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as COSV99370384; called by muse, mutect2, varscan2
- SLITRK3 | c.480C>T p.V160= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs779182058, COSV99580356; called by muse, mutect2, varscan2
- SPECC1L | c.639G>T p.L213= | Silent (SNP) | VAF 99/186 reads (53%) | catalogued as COSV100063496; called by muse, mutect2, varscan2
- SPON1 | c.1128C>A p.I376= | Silent (SNP) | VAF 114/219 reads (52%) | catalogued as rs895112796, COSV100115607; called by muse, mutect2, varscan2
- TAS2R40 | c.408G>A p.R136= | Silent (SNP) | VAF 54/121 reads (45%) | catalogued as COSV101283036; called by muse, mutect2, varscan2
- TBC1D12 | c.1557G>T p.R519= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99831896; called by muse, mutect2, varscan2
- TBX5 | c.480C>A p.L160= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100092426; called by muse, mutect2, varscan2
- TCP11L2 | c.450G>T p.R150= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100135631; called by muse, mutect2, varscan2
- TEK | c.2241G>A p.L747= | Silent (SNP) | VAF 76/117 reads (65%) | catalogued as COSV101193643; called by muse, mutect2, varscan2
- TICAM1 | c.69C>G p.L23= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs774006618, COSV99941334; called by muse, mutect2, varscan2
- TLN2 | c.2691A>C p.A897= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100170330; called by muse, mutect2, varscan2
- TMEM132D | c.3168C>T p.D1056= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as rs149201706, COSV67160949, COSV67162320; called by muse, mutect2, varscan2
- TMEM38A | c.762G>T p.G254= | Silent (SNP) | VAF 172/338 reads (51%) | catalogued as COSV99495552; called by muse, mutect2, varscan2
- TPRX1 | c.73C>A p.R25= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100445964; called by muse, mutect2
- TPSD1 | c.261C>A p.I87= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99274283; called by muse, mutect2, varscan2
- TRDN | c.711A>T p.V237= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV100523645; called by muse, mutect2, varscan2
- TROAP | c.918C>A p.P306= | Silent (SNP) | VAF 59/132 reads (45%) | catalogued as COSV99227089; called by muse, mutect2, varscan2
- TRPV5 | c.1200G>T p.L400= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99521159; called by muse, mutect2, varscan2
- TTN | c.91092C>T p.P30364= (on ENST00000591111; = p.P22940= on NM_003319.4) | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs183620684; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- TUBB | c.501C>T p.F167= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs756485442, COSV100013502; called by muse, mutect2, varscan2
- UBASH3B | c.477G>C p.S159= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99419230; called by muse, mutect2, varscan2
- UNC13C | c.5955C>A p.I1985= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99524099; called by muse, varscan2
- USH2A | c.10815T>A p.A3605= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV100244014; called by muse, mutect2, varscan2
- USH2A | c.10374G>T p.T3458= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV56381276; called by muse, mutect2, varscan2
- UVSSA | c.837C>T p.D279= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV101104636; called by muse, mutect2
- VCX | c.192A>T p.A64= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100406422; called by muse, mutect2, varscan2
- WDR64 | c.1116C>A p.I372= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs146321451, COSV100844133; called by muse, mutect2, varscan2
- WDR64 | c.2538T>C p.S846= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100844135; called by muse, mutect2
- WFDC5 | c.42T>A p.A14= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100332227; called by muse, mutect2, varscan2
- WIZ | c.4332G>T p.G1444= (on ENST00000673675 / NM_001371589.1; = p.G349= on NM_021241.3) | Silent (SNP) | VAF 24/82 reads (29%) | called by mutect2, varscan2
- ZBTB7B | c.480C>G p.R160= (on ENST00000292176; = p.R194= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/126 reads (29%) | catalogued as COSV99421692; called by muse, mutect2, varscan2
- ZNF319 | c.1095C>T p.H365= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV99540527; called by muse, mutect2, varscan2
- ZNF43 | c.531A>G p.K177= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100731996, COSV61684292; called by muse, mutect2
- ZNF44 | c.1872A>T p.R624= (on ENST00000356109 / NM_001164276.2; = p.R576= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV100633722; called by muse, mutect2, varscan2
- ACOT11 | c.1629+1010G>T | Intron (SNP) | VAF 176/356 reads (49%) | catalogued as COSV100157047; called by muse, mutect2, varscan2
- AGAP7P | n.469C>G | RNA (SNP) | VAF 31/154 reads (20%) | called by muse, mutect2, varscan2
- COL11A1 | c.898-212C>T | Intron (SNP) | VAF 36/62 reads (58%) | catalogued as COSV62184133; called by muse, mutect2, varscan2
- COL9A1 | c.781-93G>A | Intron (SNP) | VAF 27/54 reads (50%) | catalogued as COSV100295871; called by muse, mutect2, varscan2
- CPLANE1 | c.*3496G>T | 3'UTR (SNP) | VAF 72/132 reads (55%) | catalogued as COSV99952072; called by muse, mutect2, varscan2
- CR1 | c.487+12294C>G | Intron (SNP) | VAF 18/99 reads (18%) | catalogued as COSV100888100; called by muse, mutect2, varscan2
- CSNK1G2 | c.-266+11516G>T | Intron (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99730316; called by muse, mutect2, varscan2
- CST5 | c.*1G>A | 3'UTR (SNP) | VAF 35/135 reads (26%) | catalogued as COSV100489770; called by muse, mutect2, varscan2
- DCHS2 | n.6855C>A | RNA (SNP) | VAF 48/60 reads (80%) | catalogued as COSV100602850; called by muse, mutect2, varscan2
- HERC2P3 | n.2347C>T | RNA (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2
- NEURL1 | c.86-15460C>A | Intron (SNP) | VAF 10/43 reads (23%) | catalogued as rs752482725, COSV63913949; called by muse, mutect2, varscan2
- OR2U1P | n.819G>T | RNA (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- OR4C3 | c.-39G>A | 5'UTR (SNP) | VAF 44/123 reads (36%) | catalogued as rs76964780; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12809C>A | Intron (SNP) | VAF 28/77 reads (36%) | catalogued as COSV101045336, COSV67444302; called by muse, mutect2, varscan2
- SYTL2 | c.1615+1261T>C | Intron (SNP) | VAF 21/88 reads (24%) | catalogued as rs773891064, COSV100315085; called by muse, mutect2, varscan2
- TTN | c.10360+2928C>A | Intron (SNP) | VAF 29/56 reads (52%) | catalogued as COSV60194225; called by muse, mutect2, varscan2
- TTN | c.10303+1192G>A | Intron (SNP) | VAF 55/146 reads (38%) | catalogued as COSV100634768; called by muse, mutect2, varscan2
- TUBB7P | n.1211A>T | RNA (SNP) | VAF 134/174 reads (77%) | called by muse, mutect2, varscan2
- XKR6 | c.765-110462G>T | Intron (SNP) | VAF 70/109 reads (64%) | catalogued as COSV101131002; called by muse, mutect2, varscan2
